Somatic mutation profile of tumor specimen TCGA-ZH-A8Y1-01A (aliquot TCGA-ZH-A8Y1-01A-11D-A417-09) from TCGA case TCGA-ZH-A8Y1, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 74.7 years (27,279 days).
Specimen TCGA-ZH-A8Y1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cdf8fd7-f485-4c2c-b49a-4310417abf1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZH-A8Y1-10A (Blood Derived Normal), aliquot TCGA-ZH-A8Y1-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a55d8f8-35b0-4fa9-8bd2-3f99196d952a

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 8, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- DDX59 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs774555132; called by muse, mutect2, varscan2
- FBXO24 | c.1552G>A p.A518T (on ENST00000241071 / NM_033506.3; = p.A556T on NM_012172.5) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as rs1562824001; called by muse, mutect2, varscan2
- FMN2 | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs757718908; called by muse, mutect2, varscan2
- GALNT5 | c.2419A>G p.I807V | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs763038987, COSV99375359; called by muse, mutect2, varscan2
- NOTCH1 | c.4918G>A p.A1640T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs976118697, COSV53028317, COSV53052013; ClinVar: uncertain significance; called by muse, mutect2
- PBRM1 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 46/82 reads (56%) | catalogued as COSV56260223, COSV56261335; called by muse, mutect2, varscan2
- PRKG1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs749187374, COSV64777479; called by mutect2, varscan2
- ROS1 | c.4633C>T p.P1545S | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs772896918; called by muse, mutect2, varscan2
- RPS3 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV99584443; called by mutect2, varscan2
- SNPH | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV67870780; called by muse, mutect2, varscan2
- SSRP1 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53478333; called by muse, mutect2, varscan2
- UFD1 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs779950207; called by muse, mutect2, varscan2
- ASH2L | c.1817C>A p.T606N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATP1A3 | c.979C>G p.L327V (on ENST00000545399 / NM_001256214.2; = p.L314V on NM_152296.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- BIRC6 | c.788T>C p.L263S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- DPH2 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- DRC7 | c.2342A>T p.K781M | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDX | c.830T>G p.I277S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.203); called by muse, mutect2
- HNRNPA2B1 | c.74T>C p.I25T (on ENST00000354667 / NM_031243.3; = p.I13T on NM_002137.4) | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IL1F10 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2C | c.1851dup p.Q618Tfs*4 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- MAP10 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, varscan2
- MKI67 | c.948C>A p.N316K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5L2 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PHLPP1 | c.2149G>C p.A717P | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- PNLDC1 | c.1286G>T p.R429M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- REXO5 | c.1169T>C p.L390P | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RNF112 | c.1474A>G p.T492A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SLC3A2 | c.1577T>C p.L526P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SSBP2 | c.982A>G p.S328G | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.479); called by muse, mutect2
- UNC13C | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF345 | c.162A>T p.R54S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF653 | c.1607C>G p.S536C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BEST2 | c.441G>C p.V147= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- BIN1 | c.684G>A p.P228= (on ENST00000316724 / NM_001320642.1; = p.P197= on NM_004305.4) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs778962397, COSV52121662, COSV99387874; called by muse, mutect2, varscan2
- CUZD1 | c.1059C>T p.I353= | Silent (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- DNAH7 | c.4833A>G p.P1611= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs1168888944; called by muse, mutect2
- MAGED1 | c.1218A>G p.L406= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- MUC5B | c.11751A>G p.T3917= | Silent (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- MYCL | c.447C>T p.G149= (on ENST00000372816 / NM_001033081.3; = p.G179= on NM_005376.5) | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs1198540406; called by muse, mutect2
- RBMX | c.1170A>G p.R390= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV57809223; called by muse, mutect2, varscan2
- MIR450B | n.68T>C | RNA (SNP) | VAF 35/106 reads (33%) | called by muse, mutect2, varscan2
